Somatic mutation profile of tumor specimen C3N-00663-01 (aliquot CPT0087730009) from CPTAC case C3N-00663, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.6 years (14,468 days).
Specimen C3N-00663-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8001c06e-a602-42d0-a5a4-0631d9cb652c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00663-31 (Blood Derived Normal), aliquot CPT0087810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e6fa725-a3c8-4bbb-82db-e96e72e17516

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, RNA 4, Intron 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 93/275 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 203/656 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 88/272 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AIRE | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 26/381 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs531220961; called by muse, mutect2
- ARRDC2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 81/321 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.713); catalogued as rs779856527; called by muse, mutect2, varscan2
- GIMAP7 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 38/527 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV57958911; called by muse, mutect2
- IL31RA | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as rs541834884; called by muse, mutect2, varscan2
- INSR | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 69/459 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs750676016, COSV57158974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LINGO2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs867220973, COSV58058236; called by muse, varscan2
- MUC4 | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.598); catalogued as COSV62163497; called by muse, mutect2
- OR12D3 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs200720757, COSV101011043; called by muse, mutect2, varscan2
- PCDHA1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV65373693; called by muse, mutect2
- PCDHB2 | c.1538G>A p.G513D | Missense Mutation (SNP) | VAF 194/718 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782364615; called by muse, mutect2, varscan2
- RB1 | c.2486C>G p.S829* | Nonsense Mutation (SNP) | VAF 12/310 reads (4%) | catalogued as COSV57296539, COSV57308308; called by muse, mutect2
- SAGE1 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV61012464; called by muse, mutect2
- TTN | c.80548C>T p.R26850C (on ENST00000591111; = p.R19426C on NM_003319.4) | Missense Mutation (SNP) | VAF 98/327 reads (30%) | PolyPhen probably damaging (0.917); catalogued as rs746090724; called by muse, mutect2, varscan2
- ZNF264 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 106/173 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs534341211; called by muse, mutect2, varscan2
- AGAP2 | c.2567A>G p.K856R | Missense Mutation (SNP) | VAF 1495/1654 reads (90%) | SIFT tolerated (0.19); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ATRX | c.4244del p.N1415Ifs*75 | Frame Shift Del (DEL) | VAF 112/192 reads (58%) | called by mutect2, pindel, varscan2
- DGKZ | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen probably damaging (0.971); called by muse, mutect2
- FLACC1 | c.281A>T p.E94V | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPR151 | c.933A>C p.E311D | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HCAR1 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2BP1 | c.991G>C p.G331R | Missense Mutation (SNP) | VAF 102/291 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KBTBD7 | c.1134C>G p.H378Q | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2A7 | c.598G>C p.A200P | Missense Mutation (SNP) | VAF 29/784 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- PIK3R1 | c.1350_1352del p.H450_E451delinsQ (on ENST00000521381 / NM_181523.3; = p.H180_E181delinsQ on NM_181504.4) | In Frame Del (DEL) | VAF 58/196 reads (30%) | called by pindel, varscan2
- TRPM3 | c.3761A>G p.D1254G (on ENST00000357533 / NM_001366142.2; = p.D1109G on NM_020952.6) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- KCNK7 | c.660C>G p.P220= | Silent (SNP) | VAF 111/347 reads (32%) | catalogued as COSV58421725; called by muse, mutect2, varscan2
- MTRNR2L6 | c.33T>C p.L11= | Silent (SNP) | VAF 43/161 reads (27%) | called by muse, mutect2, varscan2
- MYOM1 | c.3108C>T p.I1036= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs373843049; ClinVar: likely benign; called by mutect2, varscan2
- PTPRC | c.1494T>C p.D498= | Silent (SNP) | VAF 182/441 reads (41%) | called by muse, mutect2, varscan2
- SLC16A8 | c.156C>T p.A52= | Silent (SNP) | VAF 8/169 reads (5%) | catalogued as rs1233811371; called by muse, mutect2
- DCHS2 | n.105A>G | RNA (SNP) | VAF 86/203 reads (42%) | called by muse, mutect2, varscan2
- EIF4G3 | c.300-22174C>A | Intron (SNP) | VAF 66/238 reads (28%) | catalogued as rs1192047925; called by muse, mutect2, varscan2
- IGSF1 | c.-112A>G | 5'UTR (SNP) | VAF 56/91 reads (62%) | called by muse, mutect2, varscan2
- KRT17P1 | n.366G>C | RNA (SNP) | VAF 58/294 reads (20%) | called by muse, mutect2, varscan2
- OR7A2P | n.321A>G | RNA (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- SLC25A51P4 | n.759C>A | RNA (SNP) | VAF 107/385 reads (28%) | called by muse, mutect2, varscan2
